CCDI case PBCETG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b3b35de7-bdd7-4dc2-a1d1-6e1570216e66

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,280 days).

Biospecimens (3 samples)
- Sample 0DQ7WF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
